Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FF, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FF-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name: [REDACTED]	Service: [REDACTED]	Accession #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location: [REDACTED]	Received: [REDACTED]
Gender: [REDACTED]	Facility: [REDACTED]	Reported: [REDACTED]
HCN: [REDACTED]		
Ordering MD: [REDACTED]		
Copy To: [REDACTED]		

Specimen(s) Received

1. Lymph-Node: LEFT PARATRACHEAL LYMPH NODE
2. Rt. paratracheal tissue qs
3. Parametal lobe
4. Total thyroid (suture rt lobe)
5. Rt. paratracheal lymph node

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph node, 1 (left paratracheal) biopsy
2. No pathological diagnosis: Lymph node (right paratracheal) biopsy
3. No pathological diagnosis: Thyroid (pyramidal lobe) resection specimen
4. Multifocal papillary carcinoma, dominant left 1.5 cm involving resection margin: Thyroid
No pathological diagnosis: Parathyroids, left 1, and right 1
No pathological diagnosis: Lymph node, 1
- total thyroidectomy specimen
5. No pathological diagnosis: Lymph node (right paratracheal) biopsy

ICD-0-3
carcinoma, papillary, thyroid
8260/3

Synoptic Data

Specimen Type:	Total Thyroidectomy
Tumour Focality:	Multifocal
Dominant Tumour	
Histologic Type:	Papillary carcinoma, classical type
Tumour Site:	Left Lobe
Tumour Size:	Greatest Dimension: 1.5 cm
	Additional Dimensions: 1.1 x 0.9 cm
Capsular Invasion:	Unencapsulated
	Locally invasive
Extrathyroidal Extension:	Absent
Margins:	Margin(s) involved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Present
Secondary Tumour	

Site: thyroid, nos C73.9

lw
10/2/12

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic type: Papillary carcinoma, follicular variant
Tumour Site: Left Lobe
Tumour Size: Greatest Dimension: 0.1 cm
Capsular Invasion: Unencapsulated
Extrathyroidal Extension: Absent
Margins: Margins uninvolved by carcinoma

Pathologic Staging (pTNM): pT1: Tumor size 2 cm or less, limited to thyroid
pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes
Number of regional lymph nodes examined: 4
Number of regional lymph nodes involved: 1
pMX: Distant metastasis cannot be assessed

Additional Pathologic Findings: Other (specify): Papillary microcarinoma, left 0.1 cm

Electronically verified by:

Clinical History

THYROID CA

Gross Description

1. The specimen labelled with the patient's name and as "left paratracheal lymph node" consists of a piece of brown-tan tissue that weighs 0.28 g and measures 0.3 x 0.2 x 0.3 cm.

1A submitted in

2.. The specimen labeled with the patient's name and as "right paratracheal tissue" consists of a tiny piece of tissue that measures 0.4 x 0.2 x 0.2 cm. It is frozen for intraoperative consultation.

2A frozen section block resubmitted

3. The specimen labelled with the patient's name and as "right parametral lobe" consists of a piece of brown-tan tissue that weighs 0.32 g and measures 0.3 x 0.3 x 0.3 cm.

3A submitted in

4. The specimen labeled with the patient's name and as "total thyroid suture right lobe" consists of a thyroid gland that is oriented with stitch and weighs 19.0 g. The right lobe measures 5.0 cm SI x 3.2 cm ML x 2.0 cm AP, the left lobe measures 4.0 cm SI x 2.5 cm ML x 2.0 cm AP and the isthmus measures 3.5 cm SI x 1.4 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with silver nitrate. The superior pole of the left lobe contains one nodule is well delineated and has brownish tan solid cut surfaces. The nodule measures 1.1 x 0.8 x 0.9 cm. The remainder of the thyroid tissue is brown in color, solid and homogeneous. Sections of left lobe nodule and normal tissue are stored frozen. A representative section of the nodule is also fixed for . The remainder of the specimen is submitted as follows:

4A-L right lobe, superior to inferior

4M-N isthmus

4O-X left lobe, superior to inferior

5. The specimen labelled with the patient's name and as "right paratracheal lymph node" consists of a piece of brown tan tissue that weighs 0.36 g and measures 0.6 x 0.4 x 0.4 cm.

5A submitted in

Quick Section Diagnosis

2A benign lymph node

[page 3 of 3]
Surgical Pathology Consultation Report

Dual/Synchronous Primary	NOTED	

Source: NCI Genomic Data Commons file 39695b22-86ad-4b29-a5cc-ee0dda01f2c4 (TCGA-EM-A4FF.013C1D9F-3602-413B-B211-31BE03C5C1D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).